Somatic mutation profile of tumor specimen 0DUEUE from CCDI case PBCLFH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Carcinoma, metastatic, NOS; Tissue or organ of origin: Lymph nodes of inguinal region or leg; Age at diagnosis: 12.0 years (4,385 days).
Specimen 0DUEUE: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61ec212a-5aef-4d7a-9cbf-a18a049fd6df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUETP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1ad3c39-b868-405b-b31a-11c9eac37a8c

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'UTR 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DSCAM | c.5224G>A p.A1742T | Missense Mutation (SNP) | VAF 15/368 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- PRPS1L1 | c.-1G>A | 5'UTR (SNP) | VAF 12/402 reads (3%) | called by muse, mutect2
